Gene-level copy-number profile of tumor specimen ALCH-AD75-TTR1-A from ALCHEMIST case ALCH-AD75, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.4 years (19,876 days).
Specimen ALCH-AD75-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f8ed9db9-8b9a-47d7-aa3e-e3d6c9a005df.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AD75-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/b24eaa5e-ee3a-4089-860b-a43ced36e562

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 218; copy number 1: 11,505; copy number 2: 35,185; copy number 3: 10,243; copy number 4: 992; copy number 5: 233; copy number 6: 8; copy number 7: 1; copy number 8: 2; copy number 13: 3; copy number 15: 4.

Homozygous deletions (total copy number 0; autosomes only): 216 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:170,896,929–170,904,461, 1 gene (within-gene range 0–1): AC008514.2.
- chr7:76,397,518–77,043,775, 22 genes (within-gene range 0–2): ZP3, DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16, AC004980.1, POMZP3, AC004980.2, AC006972.1, AC007003.1, DTX2P1-UPK3BP1-PMS2P11, FDPSP7, AC114737.1, DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17.
- chr7:150,484,061–150,513,839, 2 genes: AC073111.1, STRADBP1.
- chr8:33,859,480–36,779,209, 25 genes (within-gene range 0–1): AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1, UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264.
- chr8:36,795,255–36,795,862, 1 gene (within-gene range 0–2): AC124076.1.
- chr9:7,477,045–8,797,194, 9 genes (within-gene range 0–1): RPL4P5, PPIAP33, AL354694.1, DMAC1, AL135923.2, AL135923.1, AL583805.2, AL583805.1, RNU7-185P.
- chr9:8,936,079–9,091,245, 2 genes (within-gene range 0–1): AL596451.1, RPS26P3.
- chr9:20,658,309–27,066,134, 91 genes (within-gene range 0–1) (broad region; genes not listed).
- chr9:27,109,141–29,826,711, 24 genes: TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.1, AL353684.1, AL354676.1, ME2P1.
- chr10:94,688,154–95,173,187, 13 genes (within-gene range 0–2): AL583836.1, CYP2C19, MTND4P19, CYP2C58P, RPL7AP52, CYP2C9, MTND4P20, CYP2C59P, CYP2C60P, AL359672.1, CYP2C8, AL157834.4, AL157834.3.
- chr11:63,079,940–63,410,294, 8 genes: SLC22A24, RPL29P22, SLC22A10, SLC22A25, AP001880.2, CCND2P1, AP001880.1, SLC22A9.
- chr11:85,336,075–85,510,044, 3 genes (within-gene range 0–2): AP002803.1, AP003035.1, RNU6-1292P.
- chr15:46,317,393–46,351,753, 3 genes: AC091074.3, MTND5P40, AC091074.1.
- chr15:101,875,964–101,979,093, 12 genes: OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 248 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,947,301–91,723,605, 86 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr4:75,556,048–75,565,871, 1 gene, copy number 5: ODAPH.
- chr6:99,271,168–99,589,899, 9 genes, copy number 5–6 (within-gene range 4–6): FAXC, COQ3, PNISR, AL513550.1, USP45, TSTD3, Y_RNA, CCNC, AL137784.1.
- chr14:18,333,726–18,419,273, 4 genes, copy number 15: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:31,025,106–31,207,804, 4 genes, copy number 6–7 (within-gene range 4–7): AP4S1, HECTD1, RPL21P5, RNU6-541P.
- chr14:52,707,178–52,952,864, 10 genes, copy number 5–6: PSMC6, STYX, GNPNAT1, AL139317.3, AL139317.5, AL139317.1, AL139317.2, FERMT2, AL139317.4, AL352979.4.
- chr14:106,482,435–106,521,073, 7 genes, copy number 5 (within-gene range 3–5): LINC00221, IGHVIV-44-1, IGHVII-44-2, IGHV1-45, IGHV1-46, IGHVII-46-1, IGHV3-47.
- chr14:106,556,936–106,879,812, 51 genes, copy number 5: IGHV3-49, IGHVII-49-1, IGHV3-50, IGHV5-51, IGHV8-51-1, IGHVII-51-2, IGHV3-52, IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60, RNA5SP389, IGHVII-60-1, IGHV4-61, IGHV3-62, IGHVII-62-1, IGHV3-63, IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr21:7,744,962–13,120,807, 74 genes, copy number 5–13 (broad region; genes not listed).
- chr21:23,857,081–23,890,541, 2 genes, copy number 5: AP000474.2, AP000474.1.

Autosomal genes at a single copy (total copy number 1): 10,257. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
